Somatic mutation profile of tumor specimen ALCH-AENF-TTP1-A (aliquot ALCH-AENF-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AENF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,692 days).
Specimen ALCH-AENF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e4c22c0-df0c-4b30-9def-180586e595e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENF-NB1-A (Blood Derived Normal), aliquot ALCH-AENF-NB1-A-2-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ed1de18-4197-4cd2-89c2-e7b169a58d7c

The open-access MAF lists 167 somatic variants for this specimen: 109 protein-altering or splice-affecting, 36 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 36, Nonsense Mutation 14, RNA 10, Intron 6, 5'Flank 2, 5'UTR 2, Splice Region 2, 3'UTR 2, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 172/1256 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- A4GNT | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.095); catalogued as COSV52629000; called by muse, mutect2
- ADGRB3 | c.1227G>A p.W409* | Nonsense Mutation (SNP) | VAF 22/350 reads (6%) | catalogued as COSV101000350; called by muse, mutect2
- ATP2B3 | c.2506G>T p.V836F | Missense Mutation (SNP) | VAF 18/471 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54841944; called by muse, mutect2
- ATRX | c.6691C>A p.L2231M | Missense Mutation (SNP) | VAF 31/562 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV64880590; called by muse, mutect2
- ATXN3L | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66076006; called by muse, mutect2
- BOD1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53633087; called by muse, mutect2
- BPIFC | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 22/353 reads (6%) | catalogued as COSV55913203, COSV55916336; called by muse, mutect2
- CERT1 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.209); catalogued as rs1015594737; called by muse, mutect2
- CSMD3 | c.9067G>T p.G3023* (on ENST00000297405 / NM_001363185.1; = p.G2854* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 62/987 reads (6%) | catalogued as COSV52151243; called by muse, mutect2
- DCAF4L2 | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 59/767 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.269); catalogued as COSV60478173; called by muse, mutect2
- DCAF4L2 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 40/520 reads (8%) | catalogued as COSV60479690, COSV99081981; called by muse, mutect2
- DOCK3 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56549778; called by muse, mutect2
- FLG | c.4468C>G p.R1490G | Missense Mutation (SNP) | VAF 41/872 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs758833597, COSV64251257, COSV64251990; called by muse, mutect2
- GP2 | c.697G>T p.E233* (on ENST00000381362 / NM_001007240.3; = p.E230* on NM_001502.4) | Nonsense Mutation (SNP) | VAF 46/688 reads (7%) | catalogued as COSV56894269, COSV56894705; called by muse, mutect2
- IGKV1-16 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 33/521 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758361616; called by muse, mutect2
- IRAK1 | c.1991C>A p.P664H | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64111757; called by muse, mutect2
- KIF2B | c.783C>A p.N261K | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV52128606, COSV52133257; called by muse, mutect2
- KLHDC3 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 72/1245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338373118, COSV55065249; called by muse, mutect2
- KLK7 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 21/460 reads (5%) | catalogued as rs1384506878; called by muse, mutect2
- MEOX2 | c.701G>T p.W234L | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56290154; called by muse, mutect2
- MGAT5B | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV56935836; called by muse, mutect2
- NRXN3 | c.2486C>A p.S829Y (on ENST00000335750 / NM_001330195.2; = p.S456Y on NM_004796.6) | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59787110; called by muse, mutect2
- NTF3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1408813478, COSV58417724; called by muse, mutect2
- OR5D18 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61738853; called by muse, mutect2
- OR5M10 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV73242248; called by muse, mutect2
- OR6C74 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV59606924, COSV59607419; called by muse, mutect2
- OXSM | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV55002716; called by muse, mutect2
- SPTA1 | c.4737G>C p.K1579N | Missense Mutation (SNP) | VAF 115/882 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV63757962; called by muse, mutect2, varscan2
- THOC2 | c.2779G>T p.E927* | Nonsense Mutation (SNP) | VAF 20/373 reads (5%) | catalogued as COSV99833875; called by muse, mutect2
- TRO | c.3482G>T p.S1161I | Missense Mutation (SNP) | VAF 28/435 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51508565; called by muse, mutect2
- TRPM6 | c.2449G>C p.G817R | Missense Mutation (SNP) | VAF 80/1154 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62514523; called by muse, mutect2
- ZEB1 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 27/398 reads (7%) | catalogued as COSV58036207; called by muse, mutect2
- ZNF729 | c.2519G>A p.R840K | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.079); catalogued as rs770646973; called by muse, mutect2
- AHNAK2 | c.13432C>A p.P4478T | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP4 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.245); called by muse, mutect2
- ARHGEF6 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 40/1028 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- CALCRL | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.026); called by muse, mutect2
- CATSPERG | c.2706G>T p.K902N | Missense Mutation (SNP) | VAF 19/540 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.035); called by muse, mutect2
- CC2D1A | c.1710G>T p.Q570H | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.235); called by muse, mutect2
- CCBE1 | c.1049C>G p.T350S | Missense Mutation (SNP) | VAF 50/751 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- CCNB3 | c.3770A>T p.N1257I | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- CHRM2 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 37/713 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2
- CLCN3 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 25/555 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2
- COL2A1 | c.927T>A p.G309= | Splice Region (SNP) | VAF 56/1136 reads (5%) | called by muse, mutect2
- COL6A3 | c.9302C>A p.T3101K | Missense Mutation (SNP) | VAF 29/760 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2
- CPXCR1 | c.382C>A p.H128N | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2
- CSMD3 | c.9319C>A p.P3107T (on ENST00000297405 / NM_001363185.1; = p.P2938T on NM_052900.3) | Missense Mutation (SNP) | VAF 34/797 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- CSMD3 | c.9068G>T p.G3023V (on ENST00000297405 / NM_001363185.1; = p.G2854V on NM_052900.3) | Missense Mutation (SNP) | VAF 60/987 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- DCAF4L2 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 42/531 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- DCAF8L2 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 38/603 reads (6%) | called by muse, mutect2
- DMD | c.5196C>A p.D1732E | Missense Mutation (SNP) | VAF 42/667 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.214); called by muse, mutect2
- DNER | c.1505G>T p.C502F | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DOT1L | c.2554_2560del p.E852Pfs*214 | Frame Shift Del (DEL) | VAF 19/147 reads (13%) | called by mutect2, pindel, varscan2
- EDA | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 20/402 reads (5%) | called by muse, mutect2
- EDA | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM181A | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2
- FAT3 | c.2162A>G p.Q721R | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.101); called by muse, mutect2
- FAT4 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 19/400 reads (5%) | called by muse, mutect2
- FILIP1L | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.426); called by muse, mutect2
- GRB10 | c.1141G>T p.A381S (on ENST00000398812; = p.A335S on NM_001001549.3) | Missense Mutation (SNP) | VAF 58/1159 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.632); called by muse, mutect2
- HEATR3 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- HK1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 46/783 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- IGHV1-18 | c.258A>C p.R86S | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); called by muse, mutect2
- IL2RG | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 30/678 reads (4%) | called by muse, mutect2
- INHBA | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 24/466 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- IREB2 | c.2748A>T p.E916D | Missense Mutation (SNP) | VAF 19/442 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.022); called by muse, mutect2
- KCNJ2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 34/634 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- KRTAP12-1 | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 31/560 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- KYNU | c.508-2A>G p.X170_splice | Splice Site (SNP) | VAF 20/520 reads (4%) | called by muse, mutect2
- LAMA1 | c.2999G>T p.C1000F | Missense Mutation (SNP) | VAF 48/774 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYPD4 | c.426C>G p.C142W | Missense Mutation (SNP) | VAF 19/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAMLD1 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 23/758 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MMS22L | c.1877T>A p.I626K | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); called by muse, mutect2
- NEB | c.11480C>A p.A3827D | Missense Mutation (SNP) | VAF 29/333 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEGR1 | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.403); called by muse, mutect2
- NKRF | c.1997A>T p.K666M | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2
- NTHL1 | c.511A>G p.T171A (on ENST00000219066; = p.T163A on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2
- OGT | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.902); called by muse, mutect2
- OR8K3 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTOR | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- OTUD5 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB5 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); called by muse, mutect2
- PEX2 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.233); called by muse, mutect2
- PRR23B | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.347); called by muse, mutect2
- PRSS38 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 54/674 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); called by muse, mutect2
- SCAI | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 46/800 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SCN3A | c.4659C>A p.Y1553* | Nonsense Mutation (SNP) | VAF 36/676 reads (5%) | called by muse, mutect2
- SH3KBP1 | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- SLC12A1 | c.2298C>A p.A766= | Splice Region (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- SLC25A53 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2
- SLX4 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 51/942 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- SSTR5 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 23/367 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SYNE1 | c.24389A>T p.Q8130L (on ENST00000367255 / NM_182961.4; = p.Q8059L on NM_033071.3) | Missense Mutation (SNP) | VAF 24/639 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TECPR2 | c.2693C>T p.A898V | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- TLL2 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- TMPRSS11A | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 44/752 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TOGARAM1 | c.3139T>G p.S1047A | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- TYSND1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- UHRF1BP1L | c.281G>C p.C94S | Missense Mutation (SNP) | VAF 19/554 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UNC80 | c.122A>C p.Q41P | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- XIRP1 | c.1112A>C p.E371A | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- XK | c.1325G>C p.C442S | Missense Mutation (SNP) | VAF 33/573 reads (6%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- XKR4 | c.1254C>A p.H418Q | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.998); called by muse, mutect2
- XRN1 | c.1325T>G p.M442R | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- ZC3H12B | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- ZNF536 | c.1073G>T p.W358L | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF608 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.347); called by muse, mutect2
- ZNF729 | c.2882A>G p.K961R | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- ADCY2 | c.1977T>A p.S659= | Silent (SNP) | VAF 21/329 reads (6%) | called by muse, mutect2
- ANKRD35 | c.2380C>A p.R794= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV62910323; called by muse, mutect2, varscan2
- ANO2 | c.2379C>G p.T793= (on ENST00000356134 / NM_001278597.3; = p.T797= on NM_001278596.3) | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- ARID4B | c.1863A>G p.A621= | Silent (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2
- CASP8AP2 | c.4086A>T p.L1362= | Silent (SNP) | VAF 20/442 reads (5%) | called by muse, mutect2
- CCSER2 | c.801A>T p.S267= | Silent (SNP) | VAF 20/380 reads (5%) | called by muse, mutect2
- CHAT | c.138C>T p.G46= | Silent (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- CLCN1 | c.2748C>A p.A916= | Silent (SNP) | VAF 24/634 reads (4%) | called by muse, mutect2
- CNOT1 | c.4098C>T p.S1366= | Silent (SNP) | VAF 36/541 reads (7%) | called by muse, mutect2
- CPPED1 | c.315G>C p.T105= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- CSMD1 | c.5143C>A p.R1715= (on ENST00000520002; = p.R1714= on NM_033225.6) | Silent (SNP) | VAF 18/418 reads (4%) | catalogued as COSV59290442; called by muse, mutect2
- DRP2 | c.2517C>A p.A839= | Silent (SNP) | VAF 32/716 reads (4%) | called by muse, mutect2
- DYNC2H1 | c.10950T>A p.T3650= | Silent (SNP) | VAF 44/542 reads (8%) | called by muse, mutect2
- EDA | c.27G>A p.R9= | Silent (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- F8 | c.5916C>A p.I1972= | Silent (SNP) | VAF 14/334 reads (4%) | catalogued as COSV64276008; called by muse, mutect2
- GPR101 | c.1242C>G p.P414= | Silent (SNP) | VAF 20/385 reads (5%) | catalogued as COSV99981612; called by muse, mutect2
- GZMA | c.24G>A p.L8= | Silent (SNP) | VAF 26/552 reads (5%) | called by muse, mutect2
- IGHA2 | c.744G>T p.L248= | Silent (SNP) | VAF 20/450 reads (4%) | catalogued as rs1180202128; called by muse, mutect2
- IGSF1 | c.1428G>A p.G476= | Silent (SNP) | VAF 20/510 reads (4%) | called by muse, mutect2
- INSYN2A | c.478C>A p.R160= | Silent (SNP) | VAF 50/479 reads (10%) | catalogued as COSV54728925; called by muse, mutect2, varscan2
- NUP54 | c.1002C>T p.L334= | Silent (SNP) | VAF 18/530 reads (3%) | called by muse, mutect2
- OR2L13 | c.819G>C p.L273= | Silent (SNP) | VAF 52/598 reads (9%) | called by muse, mutect2
- OR2L8 | c.354C>A p.A118= | Silent (SNP) | VAF 58/614 reads (9%) | catalogued as rs968512143; called by muse, mutect2
- OR4C6 | c.411G>A p.R137= | Silent (SNP) | VAF 19/340 reads (6%) | catalogued as COSV58605066; called by muse, mutect2
- OXCT1 | c.1482A>T p.T494= | Silent (SNP) | VAF 58/950 reads (6%) | called by muse, mutect2
- PLA2R1 | c.3447G>A p.L1149= | Silent (SNP) | VAF 46/834 reads (6%) | catalogued as COSV51779348; called by muse, mutect2
- SLC37A3 | c.462G>A p.L154= | Silent (SNP) | VAF 36/738 reads (5%) | catalogued as rs1258574784; called by muse, mutect2
- TDRD15 | c.360G>T p.R120= | Silent (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- TENM1 | c.5427G>A p.K1809= | Silent (SNP) | VAF 17/256 reads (7%) | called by muse, mutect2
- TFE3 | c.63C>A p.A21= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TTC8 | c.945A>C p.A315= (on ENST00000338104 / NM_001288781.1; = p.A299= on NM_144596.4) | Silent (SNP) | VAF 24/538 reads (4%) | called by muse, mutect2
- VAMP7 | c.288A>G p.T96= | Silent (SNP) | VAF 34/554 reads (6%) | catalogued as rs751276633; called by muse, mutect2
- WDR97 | c.1785G>T p.A595= | Silent (SNP) | VAF 25/327 reads (8%) | called by muse, mutect2
- XRN1 | c.1323G>A p.K441= | Silent (SNP) | VAF 16/361 reads (4%) | catalogued as COSV53808094; called by muse, mutect2
- ZFHX4 | c.3072G>A p.E1024= | Silent (SNP) | VAF 37/648 reads (6%) | called by muse, mutect2
- ZNF157 | c.786G>A p.T262= | Silent (SNP) | VAF 12/278 reads (4%) | catalogued as rs1370512145; called by muse, mutect2
- AC034198.1 | n.178C>A | RNA (SNP) | VAF 45/745 reads (6%) | called by muse, mutect2
- AC093791.1 | n.332G>A | RNA (SNP) | VAF 22/396 reads (6%) | called by muse, mutect2
- AC134312.1 | n.1327T>A | RNA (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- ACLY | chr17:41918975 G>T | 5'Flank (SNP) | VAF 16/276 reads (6%) | called by muse, mutect2
- ADCYAP1R1 | c.1047-3099A>G | Intron (SNP) | VAF 25/448 reads (6%) | called by muse, mutect2
- CCDC144NL | n.623C>G | RNA (SNP) | VAF 32/510 reads (6%) | catalogued as rs1020892974; called by muse, mutect2
- CFL2 | c.*400G>A | 3'UTR (SNP) | VAF 58/1180 reads (5%) | called by muse, mutect2
- CHRNA4 | c.*69G>T | 3'UTR (SNP) | VAF 45/574 reads (8%) | called by muse, mutect2
- DCTN1 | c.3211+20G>T | Intron (SNP) | VAF 35/506 reads (7%) | catalogued as COSV62621421; called by muse, mutect2
- DENND2D | chr1:111204335 G>A | 5'Flank (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- FAM172BP | n.514G>A | RNA (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- FLJ40288 | n.883C>A | RNA (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- HSPA7 | n.281T>A | RNA (SNP) | VAF 52/891 reads (6%) | called by muse, mutect2
- HTR3A | c.265-44G>A | Intron (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- NAV3 | c.2024-12932C>A | Intron (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- NXF5 | n.1891G>A | RNA (SNP) | VAF 22/532 reads (4%) | called by muse, mutect2
- OR2L1P | n.563G>C | RNA (SNP) | VAF 70/792 reads (9%) | called by muse, mutect2
- PLIN5 | c.-15C>T | 5'UTR (SNP) | VAF 16/354 reads (5%) | catalogued as rs1395450530; called by muse, mutect2
- SCP2D1-AS1 | n.199C>A | RNA (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- STX5 | c.-116G>T | 5'UTR (SNP) | VAF 19/298 reads (6%) | catalogued as COSV53681318; called by muse, mutect2
- TGFBR3 | c.738-15G>T | Intron (SNP) | VAF 32/536 reads (6%) | called by muse, mutect2
- TTN | c.10360+1896T>C | Intron (SNP) | VAF 6/94 reads (6%) | catalogued as rs1183473586; called by muse, mutect2
